Surgical pathology report (de-identified scan), TCGA case TCGA-G7-A8LC, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-G7-A8LC-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, papillary renal
cell 8260/3
Site @ Kidney NOS C64.9
JW 11/24/13

SPECIMENS:

- A. RIGHT RENAL TUMOR BASE
- B. RIGHT KIDNEY TUMOR

SPECIMEN(S):

- A. RIGHT RENAL TUMOR BASE
- B. RIGHT KIDNEY TUMOR

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA-right renal tumor base: No malignancy identified.
Diagnosis called by Dr. to Dr. at

DIAGNOSIS:

- A. KIDNEY, RIGHT, TUMOR BASE, EXCISION:
- NEGATIVE FOR CARCINOMA
- B. KIDNEY, RIGHT, PARTIAL NEPHRECTOMY:
- PAPILLARY RENAL CELL CARCINOMA, TYPE 2
- TUMOR SIZE: 2.5 CM IN GREATEST DIMENSION
- SURGICAL RESECTION MARGIN IS INVOLVED BY CARCINOMA.
- SEE SYNOPTIC REPORT

COMMENT:

The surface inked orange is not real margin as per conversation with Dr. on
SYNOPTIC REPORT - KIDNEY (PARTIAL OR RADICAL)

Specimens Involved

Specimens: A: RIGHT RENAL TUMOR BASE

B: RIGHT KIDNEY TUMOR

Specimen Type: Partial nephrectomy

Without adrenal gland

Laterality: Right

Tumor Site: Not specified

Focality: Unifocal

Tumor Size (largest tumor if multiple): Greatest dimension: 2.5cm

Macroscopic Extent of Tumor: Tumor limited to kidney

WHO CLASSIFICATION

Papillary renal cell carcinoma 8260/3

Histologic Grade (Fuhrman Nuclear Grade): G2: Nuclei slightly irregular, approximately 15 u;
nucleoli evident

Invasion of Vascular/Lymphatic: Absent

Perinephric Tissue Invasion: Absent

Margins: Margin(s) involved by invasive carcinoma

Include: Renal parenchymal margin (partial nephrectomy only)

Adrenal Gland: Not present

Regional Lymph Nodes: None sampled

Additional Findings: None identified

Pathological Staging (pTNM): pT 1a N x M x

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

pMX: Cannot be assessed

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block B2

Population: Tumor Cells

Stain/Marker:Result: Comment:

[page 2 of 2]
IHPAA Discrepancy		

Source: NCI Genomic Data Commons file aa13e142-2265-473f-b7ea-3ae034912c0c (TCGA-G7-A8LC.A3E4073B-A147-4E07-B3F2-1FEB1FB7523E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).